MMRF case MMRF_1831 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f65642a5-65a1-49d6-b42f-6455c88f8c5e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.4 years (25,346 days); ISS stage: I; Days to last known disease status: 1,088 days (3.0 years); Days to last follow up: 1,088 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: Liposomal Doxorubicin Regimen; Days to treatment start: 2 days; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 204 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,088.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 37.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 21.3 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 3.37 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 8 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 6.49 mmol/L.
- Day 100 (ECOG 0): M Protein 0.1 g/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 38.7 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 8.75 ×10⁹/L; Platelets 63 ×10⁹/L; Creatinine 249 µmol/L; Blood Urea Nitrogen 18.6 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 4.24 mmol/L.
- Day 198 (ECOG 1): Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6.42 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.66 mmol/L.
- Day 254 (ECOG 1): Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.22 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6.49 mmol/L.
- Day 338 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 3.29 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.94 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 422 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 7.13 g/L; Immunoglobulin A 7.13 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 3.15 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7.92 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 8.47 mmol/L.
- Day 520 (ECOG 0): Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 4.38 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 9.5 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 7.87 mmol/L.
- Day 660 (ECOG 0): Lactate Dehydrogenase 4.68 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 12.8 ×10⁹/L; Absolute Neutrophil 11.7 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 9.46 mmol/L.
- Day 744 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.58 g/L; Beta 2 Microglobulin 4.6 µg/mL; Lactate Dehydrogenase 4.82 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 8.96 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 8.97 mmol/L.
- Day 786 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 4.28 µg/mL; Lactate Dehydrogenase 5.5 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 8.65 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 9.68 mmol/L.
- Day 870 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 5.32 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 3.82 µg/mL; Lactate Dehydrogenase 4.48 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6.38 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 10.1 mmol/L.
- Day 990 (ECOG 1): Hemoglobin 6.14 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 10.5 ×10⁹/L; Platelets 155 ×10⁹/L.
- Day 1,038 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 6.88 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.66 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 9.41 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Glucose 6.71 mmol/L.

Other clinical attributes
- Day -3: Weight: 99 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1831_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1831_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
